Somatic mutation profile of tumor specimen C3L-01330-01 (aliquot CPT0083390007) from CPTAC case C3L-01330, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 68.7 years (25,076 days).
Specimen C3L-01330-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fce829d-2d35-4ae7-a187-3bec32a78b63.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01330-32 (Blood Derived Normal), aliquot CPT0081800001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e9165c1-34ad-4359-9fee-cca0d0dd62e1

The open-access MAF lists 60 somatic variants for this specimen: 39 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Splice Site 4, Nonsense Mutation 2, 3'UTR 2, Frame Shift Ins 1, 5'Flank 1, RNA 1, Splice Region 1, 3'Flank 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 104/484 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- AC092143.1 | c.1762C>T p.R588C | Missense Mutation (SNP) | VAF 82/422 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as rs751967547, COSV59249246; called by muse, mutect2, varscan2
- CPS1 | c.2324G>A p.R775H | Missense Mutation (SNP) | VAF 42/262 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766970243, COSV51816792; called by muse, mutect2, varscan2
- FLOT2 | c.8A>G p.N3S | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.063); catalogued as rs199799580; called by muse, mutect2, varscan2
- GRIK3 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 11/144 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.396); catalogued as rs773388016, COSV66145236; called by muse, mutect2
- LAMA1 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 38/318 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748576952, COSV67532554; called by muse, mutect2, varscan2
- LAMB1 | c.1897C>T p.R633* | Nonsense Mutation (SNP) | VAF 10/248 reads (4%) | catalogued as rs1369428503, COSV99741114; called by muse, mutect2
- LIME1 | c.434A>G p.Y145C | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as rs1412305318; called by muse, mutect2, varscan2
- OR2T6 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV104418567, COSV63216612; called by muse, mutect2, varscan2
- PRDM1 | c.133G>A p.D45N | Missense Mutation (SNP) | VAF 24/317 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.584); catalogued as COSV100959410; called by muse, mutect2
- RILPL1 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 19/148 reads (13%) | catalogued as rs1433531406; called by muse, mutect2, varscan2
- ROS1 | c.2050G>A p.D684N | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.888); catalogued as COSV63854351; called by muse, mutect2, varscan2
- SLC12A3 | c.2303A>G p.N768S | Missense Mutation (SNP) | VAF 50/387 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs574853861, CD982948; called by muse, mutect2, varscan2
- SLC45A4 | c.970C>G p.L324V (on ENST00000517878 / NM_001286646.2; = p.L273V on NM_001080431.2) | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.272); catalogued as COSV50149667; called by muse, mutect2, varscan2
- SMG1 | c.4273G>A p.G1425S | Missense Mutation (SNP) | VAF 59/231 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as rs755546459; called by muse, mutect2, varscan2
- TLN1 | c.4116G>T p.T1372= | Splice Region (SNP) | VAF 18/113 reads (16%) | catalogued as rs780500400; called by muse, mutect2, varscan2
- UTRN | c.9790G>A p.E3264K | Missense Mutation (SNP) | VAF 16/145 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs768832466, COSV62312965; called by muse, mutect2, varscan2
- ZNF646 | c.5224C>T p.R1742W | Missense Mutation (SNP) | VAF 14/196 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1229044813; called by muse, mutect2
- ALCAM | c.1027A>T p.T343S | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- ANKRD30B | c.478T>G p.S160A | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.192); called by muse, mutect2
- ARHGEF15 | c.1519T>C p.Y507H | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRCA2 | c.426-1G>C p.X142_splice | Splice Site (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- CNTNAP1 | c.1329_1337del p.F443_E446delinsL | In Frame Del (DEL) | VAF 28/194 reads (14%) | called by mutect2, pindel*, varscan2
- CSMD3 | c.9103T>G p.C3035G (on ENST00000297405 / NM_001363185.1; = p.C2866G on NM_052900.3) | Missense Mutation (SNP) | VAF 58/685 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- CXorf66 | c.593G>T p.C198F | Missense Mutation (SNP) | VAF 34/221 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- JUN | c.229dup p.E77Gfs*30 | Frame Shift Ins (INS) | VAF 18/107 reads (17%) | called by mutect2, pindel, varscan2
- LRRC49 | c.921+1_921+3del p.X307_splice | Splice Site (DEL) | VAF 19/68 reads (28%) | called by mutect2, pindel, varscan2
- LY75-CD302 | c.5281G>A p.D1761N | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- MEGF6 | c.3073A>T p.M1025L | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- MYO1G | c.2317G>A p.V773M | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- OBSL1 | c.5183T>G p.V1728G | Missense Mutation (SNP) | VAF 38/188 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- PIAS1 | c.829-4_829delinsTTATT p.X277_splice | Splice Site (ONP) | VAF 4/50 reads (8%) | called by mutect2*, pindel
- PIN4 | c.352T>G p.*118Eext*15 (on ENST00000652108; = p.*134Eext*15 on NM_001170747.1) | Nonstop Mutation (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- PKN2 | c.1804-21_1810del p.X602_splice | Splice Site (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- PROCR | c.416C>T p.S139F | Missense Mutation (SNP) | VAF 55/448 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- SH3PXD2B | c.463G>A p.E155K | Missense Mutation (SNP) | VAF 13/422 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- TENM1 | c.4745G>T p.S1582I | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); called by muse, mutect2, varscan2
- UBE3B | c.1697T>C p.F566S | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZSCAN31 | c.847A>T p.N283Y | Missense Mutation (SNP) | VAF 32/185 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- ABHD3 | c.15C>T p.A5= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs762710772; called by muse, mutect2, varscan2
- CACNA1B | c.4740C>T p.R1580= | Silent (SNP) | VAF 12/121 reads (10%) | catalogued as COSV53150363; called by muse, mutect2
- CMTM5 | c.316C>T p.L106= | Silent (SNP) | VAF 18/182 reads (10%) | called by muse, mutect2
- GAA | c.2418G>A p.T806= | Silent (SNP) | VAF 28/279 reads (10%) | catalogued as rs371528938; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- IQGAP2 | c.2280G>T p.L760= | Silent (SNP) | VAF 5/97 reads (5%) | catalogued as rs1455285063, COSV57171146; called by muse, mutect2
- MAP4K2 | c.1116C>G p.V372= | Silent (SNP) | VAF 5/138 reads (4%) | called by muse, mutect2
- METTL23 | c.165G>A p.L55= | Silent (SNP) | VAF 44/427 reads (10%) | catalogued as rs1464429169; called by muse, mutect2
- NUMB | c.1146T>A p.T382= (on ENST00000355058; = p.T371= on NM_003744.5) | Silent (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- PLXDC2 | c.1104C>T p.D368= | Silent (SNP) | VAF 23/98 reads (23%) | called by muse, mutect2, varscan2
- SDHA | c.954C>T p.L318= | Silent (SNP) | VAF 72/540 reads (13%) | catalogued as rs1412623947; ClinVar: likely benign; called by muse, mutect2, varscan2
- SLC4A1 | c.894C>T p.A298= | Silent (SNP) | VAF 63/279 reads (23%) | called by muse, mutect2, varscan2
- SLITRK2 | c.990C>T p.Y330= | Silent (SNP) | VAF 39/321 reads (12%) | catalogued as COSV100158287; called by muse, mutect2, varscan2
- SPINT1 | c.108G>C p.G36= | Silent (SNP) | VAF 35/201 reads (17%) | called by muse, mutect2, varscan2
- TANC1 | c.4245G>A p.E1415= | Silent (SNP) | VAF 82/260 reads (32%) | called by muse, mutect2, varscan2
- ADAM9 | c.*657C>G | 3'UTR (SNP) | VAF 10/77 reads (13%) | called by muse, mutect2, varscan2
- GFRA1 | c.*36G>T | 3'UTR (SNP) | VAF 25/159 reads (16%) | catalogued as COSV100816296, COSV62605753; called by muse, mutect2, varscan2
- KRT6A | c.912+16A>G | Intron (SNP) | VAF 61/479 reads (13%) | called by muse, mutect2, varscan2
- MOB2 | chr11:1469902 T>G | 3'Flank (SNP) | VAF 46/184 reads (25%) | called by muse, mutect2, varscan2
- SAMHD1 | c.-67T>A | 5'UTR (SNP) | VAF 12/292 reads (4%) | called by muse, mutect2
- SSPOP | n.11266C>T | RNA (SNP) | VAF 10/57 reads (18%) | catalogued as rs938888947; called by muse, mutect2, varscan2
- TRIM74 | chr7:72970013 G>A | 5'Flank (SNP) | VAF 49/422 reads (12%) | called by muse, varscan2
